Surgical pathology report (de-identified scan), TCGA case TCGA-69-8453, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-8453-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

De-identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] M

SPECIMEN SUBMITTED:

Part A: 4R

Part B: #7

Part C: RIGHT LOWER LOBE WEDGE OF
SUPERIOR SEGMENT

Part D: PLEURA ADJACENT TO RIGHT
LOWER LOBE

Part E: LEVEL 11

Part F: #7

Part G: R9

Part H: R8

Part I: 11R

Part J: #7

Part K: #7

Part L: #12

Final Diagnosis

1. Lymph nodes, 4R, #7, level 11, #7, R9, R8, 11R, #7, #7, #12, excision (A-B, E-N) - Lymph nodes, negative for neoplasm.
2. Right lung, lower lobe, superior segment, segmentectomy (C) - Mucinous adenocarcinoma, acinar-predominant (see comment).
- Centrilobular emphysema with fibroelastosis.
- Extensive chronic bronchiolitis with rare ill-formed non-necrotizing granulomas.
- Organizing acute fibrinous pleuritis.
- Peribronchial lymph nodes, negative for neoplasm.
3. Pleural adjacent to right lower lobe, excision (D) - Organizing acute fibrinous pleuritis.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

Tumor Location: Right lower lobe, superior segment

Tumor Size: 7.5 x 6.4 x 4.7 cm

Vascular Invasion: Negative

Lymphatic Invasion: Present

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: The tumor invades into the visceral pleura but is not present at the pleural surface.

Pathologic Stage (AJCC): p Stage IIIA (T3 N0 MX).

Intraoperative Diagnosis:

A. Lymph node, negative for malignancy

B. Lymph node, negative for malignancy

C. Negative for malignancy

Clinical Diagnosis:

LUNG CA

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh for frozen section labeled "4R" are multiple fragments of brown-black soft tissue aggregating to 1.7 x 1.4 x 0.2 cm. Totally submitted in cassette A1 for frozen section.

B. Received fresh frozen section labeled "7" are multiple fragments of red soft tissue measuring 1.3 x 0.3 x 0.3 cm in aggregate. Totally submitted in cassette B1 for frozen section.

C. Received in formalin labeled "right lower lobe wedge of superior segment" is a specimen consisting of a large pulmonary wedge weighing 223 grams, and measuring 13 x 11 x 4.5 cm. A bronchial remnant measures 1.2 cm in diameter and 0.3 cm in length. The pleural surface shows adhesions and an area of puckering with underlying firm mass. Three stapled margins are present measuring 3, 4 and 6.5 cm in length and are inked orange. The pleural surface overlying the mass is inked blue. On sectioning, a fleshy tan lobulated mass measuring 7.5 x 6.4 x 4.7 cm is present abutting the pleura with pleural puckering and thickened. The mass is located 0.6 cm from the closest resection margin and 0.5 cm from bronchial margin. The remainder of the uninvolved parenchyma is pink-red. Sections are submitted as follows: C1 bronchial margin for frozen evaluation, C2 vascular margin, C3-C6 tumor with overlying pleura, C7 tumor in relation to bronchus, C8-C9 tumor with closest resection margin (orange), C10 tumor, C11 uninvolved lung parenchyma, C12-C13 bronchial lymph nodes.

D. Received in formalin labeled "pleura adjacent to right lower lobe" is an irregular segment of pleura with adhered soft tissue measuring 12 x 6 x 0.5 cm. Cross sections reveal an unremarkable cut surface. Representative sections are submitted in formalin in cassettes D1 and D2.

E. Received fresh on Telfa gauze labeled "Level 11" is a tan anthracotic nodule measuring 0.4 x 0.3 x 0.2 cm. The specimen is totally submitted in cassette E1.

F. Received fresh on Telfa gauze labeled "#7" are multiple irregular anthracotic nodules aggregating to 2 x 2 x 0.5 cm. The specimen is totally submitted in formalin in cassette F1.

G. Received fresh on Telfa gauze labeled "R9" is a solitary irregular anthracotic nodule measuring 0.7 x 0.5 x 0.5 cm. The specimen is totally submitted in cassette G1.

H. Received fresh on Telfa gauze labeled "R8" is a anthracotic nodule envelope and soft yellow adipose tissue measuring 1.5 x 1 x 0.5 cm. The specimen is totally submitted in cassette H1.

I. Received fresh on Telfa gauze labeled "11R" is a solitary anthracotic nodule measuring 1 x 0.7 x 0.5 cm. The nodule is totally submitted in formalin in cassette I1.

J. Received fresh on Telfa gauze labeled "#7" are multiple irregular anthracotic nodules aggregating to 2 x 0.5 x 0.4 cm.. The nodules are totally submitted in formalin in cassette J1.

K. Received fresh on Telfa gauze labeled "#7" is a gray soft nodule measuring 0.8 x 0.5 x 0.4 cm. The nodules are totally submitted in formalin in cassette K1.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

L. Received fresh on Telfa gauze labeled "#12" are multiple irregular anthracotic nodules aggregating to 1.5 x 1 x 0.6 cm. The nodules are totally submitted in formalin in cassette L1.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file c5f90473-fe3e-4288-b452-fab6ffeb565e (TCGA-69-8453.3F4D0319-89C9-4256-B43C-C0B1514C4380.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).